Gene-level copy-number profile of specimen HCM-CSHL-0381-C20-85A from HCMI case HCM-CSHL-0381-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.8 years (17,107 days).
Specimen HCM-CSHL-0381-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dcb02d4e-9de9-4ce4-a55a-bc7612ffb21e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0381-C20-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/091722cf-da2c-43e6-9372-628d1f693ffc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 7,691; copy number 2: 47,079; copy number 3: 3,058; copy number 4: 78; copy number 5: 475.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:73,537,143–73,543,796, 2 genes (within-gene range 0–1): ACOT1, NT5CP2.
- chr18:3,496,032–4,459,458, 15 genes: DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–1): AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 475 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:73,640,479–88,409,223, 292 genes, copy number 5 (broad region; genes not listed).
- chr11:89,700,764–98,945,079, 182 genes, copy number 5 (broad region; genes not listed).
- chr20:30,214,765–30,214,976, 1 gene, copy number 5: CFTRP3.

Autosomal genes at a single copy (total copy number 1): 7,686. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
